Somatic mutation profile of tumor specimen 0DBPQQ from CCDI case PBBLNJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.9 years (2,536 days).
Specimen 0DBPQQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a51d7a5-78ce-4f55-8b3d-0e391ff35de6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBPQR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e913c686-f71d-4557-aab6-d37672f71423

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 5'UTR 2, Intron 2, Frame Shift Del 1, 3'UTR 1, 3'Flank 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP11A | c.1441G>A p.V481I | Missense Mutation (SNP) | VAF 430/987 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.327); catalogued as rs766683009, COSV52121795; called by muse, mutect2, varscan2
- MUC5B | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 455/1174 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as rs774531281, COSV71593181; called by muse, mutect2
- RFX1 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 256/680 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.989); catalogued as rs762098757, COSV99586092; called by muse, varscan2
- ASPM | c.2072A>T p.Y691F | Missense Mutation (SNP) | VAF 30/1216 reads (2%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, mutect2
- EGLN1 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 28/822 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2
- EPRS1 | c.2542G>C p.A848P | Missense Mutation (SNP) | VAF 54/542 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.633); called by muse, varscan2
- GPR179 | c.2863C>A p.L955I (on ENST00000621958; = p.L954I on NM_001004334.4) | Missense Mutation (SNP) | VAF 251/628 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2652A>G p.I884M | Missense Mutation (SNP) | VAF 45/1592 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2
- PHF6 | c.676_680dup p.L228Efs*53 (on ENST00000332070 / NM_032458.3; = p.L229Efs*66 on NM_032335.3) | Frame Shift Ins (INS) | VAF 253/288 reads (88%) | called by mutect2, varscan2
- SLC10A4 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 122/400 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLC26A2 | c.153_157del p.Y51* | Frame Shift Del (DEL) | VAF 290/714 reads (41%) | called by mutect2, varscan2
- CBFB | c.166-68A>G | Intron (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 10/95 reads (11%) | catalogued as COSV99987084; called by muse, varscan2
- FTHL18 | n.276C>T | RNA (SNP) | VAF 347/400 reads (87%) | called by muse, mutect2, varscan2
- FUT10 | c.*77T>G | 3'UTR (SNP) | VAF 8/64 reads (13%) | called by muse, varscan2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 32/328 reads (10%) | catalogued as rs926414386, COSV100695372; called by muse, varscan2
- NRCAM | c.-58T>G | 5'UTR (SNP) | VAF 32/320 reads (10%) | called by muse, varscan2
- RNU6-1178P | chr17:20893446 G>C | 3'Flank (SNP) | VAF 40/1185 reads (3%) | catalogued as rs1315893996; called by muse, mutect2
